Somatic mutation profile of tumor specimen 0DC6NU from CCDI case PBBMAX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,431 days).
Specimen 0DC6NU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2085b8b-e6dc-4643-a358-d62449604375.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC6O1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88f97cde-6b86-42b9-a7ff-deed1d7a269d

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 2, Splice Region 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELOA3D | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 94/1042 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs557249357; called by muse, varscan2
- FAM135B | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 292/819 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99423840; called by muse, varscan2
- GLRA4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs754281260; called by muse, varscan2
- NAV3 | c.6842G>A p.G2281E (on ENST00000397909 / NM_001024383.2; = p.G2259E on NM_014903.6) | Missense Mutation (SNP) | VAF 134/1283 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777924409; called by muse, varscan2
- NPY4R | c.-57G>A | Splice Region (SNP) | VAF 6/58 reads (10%) | catalogued as rs546799762, COSV65398510; called by muse, varscan2
- P2RX6 | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 260/776 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs369700306; called by muse, varscan2
- PNMA5 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 222/482 reads (46%) | catalogued as rs1486618247, COSV62625388; called by muse, varscan2
- SOAT2 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 151/892 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs747295597, COSV100037138; called by muse, varscan2
- SVEP1 | c.8177G>A p.G2726D | Missense Mutation (SNP) | VAF 127/597 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424002115; called by muse, varscan2
- FREM2 | c.3309G>C p.L1103F | Missense Mutation (SNP) | VAF 110/1008 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, varscan2
- NAV3 | c.2594T>G p.I865S | Missense Mutation (SNP) | VAF 356/1706 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, varscan2
- PCSK5 | c.5292G>T p.W1764C | Missense Mutation (SNP) | VAF 214/982 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); called by muse, varscan2
- RBM11 | c.530T>A p.V177D | Missense Mutation (SNP) | VAF 230/2165 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, varscan2
- SRGAP1 | c.2750G>C p.S917T | Missense Mutation (SNP) | VAF 62/478 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.018); called by muse, varscan2
- FAM184B | c.723C>T p.S241= | Silent (SNP) | VAF 74/702 reads (11%) | called by muse, varscan2
- GPS1 | c.402G>A p.T134= | Silent (SNP) | VAF 570/1199 reads (48%) | catalogued as rs1381379356; called by muse, varscan2
- TOPBP1 | c.2664C>T p.S888= | Silent (SNP) | VAF 680/1833 reads (37%) | catalogued as COSV53440736; called by muse, varscan2
- UBE2O | c.3393T>C p.F1131= | Silent (SNP) | VAF 133/1330 reads (10%) | catalogued as rs767038815; called by muse, varscan2
- ZNF792 | c.156G>A p.S52= | Silent (SNP) | VAF 128/368 reads (35%) | catalogued as rs199630450, COSV68693194; called by muse, varscan2
- CNDP1 | c.1457+14T>G | Intron (SNP) | VAF 91/604 reads (15%) | called by muse, varscan2
- LATS2 | c.*38G>C | 3'UTR (SNP) | VAF 68/193 reads (35%) | called by muse, varscan2
- MYH11 | c.5296-96C>T | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs1334334098; called by muse, varscan2
